Somatic mutation profile of tumor specimen TCGA-A5-A0GA-01A (aliquot TCGA-A5-A0GA-01A-11W-A062-09) from TCGA case TCGA-A5-A0GA, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 67.5 years (24,659 days).
Specimen TCGA-A5-A0GA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27a7402d-fe74-4a87-b655-91665ebedeff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0GA-10A (Blood Derived Normal), aliquot TCGA-A5-A0GA-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/052a37ce-76f5-4999-8576-4a5e99ed2df1

The open-access MAF lists 374 somatic variants for this specimen: 293 protein-altering or splice-affecting, 72 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 202, Silent 72, Frame Shift Del 61, Nonsense Mutation 12, Frame Shift Ins 10, Intron 3, In Frame Del 3, Splice Site 3, 3'Flank 3, RNA 2, Splice Region 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 133/488 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50461516; called by muse, mutect2, varscan2
- FBXL3 | c.884del p.L295Yfs*25 | Frame Shift Del (DEL) | VAF 48/182 reads (26%) | catalogued as rs764008859; ClinVar: pathogenic; called by mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 14/91 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 83/336 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs772110575, COSV55879949, COSV56003293; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SERPINA1 | c.1158del p.E387Rfs*11 | Frame Shift Del (DEL) | VAF 23/121 reads (19%) | catalogued as rs764325655, CD890162; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- TSC1 | c.1257del p.R420Gfs*20 | Frame Shift Del (DEL) | VAF 40/174 reads (23%) | catalogued as rs118203506, CD991903; ClinVar: not provided / pathogenic; called by mutect2, pindel, varscan2
- ABCA9 | c.4698G>T p.Q1566H | Missense Mutation (SNP) | VAF 167/659 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV60630357; called by muse, mutect2, varscan2
- ABCC1 | c.3626G>A p.C1209Y | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV60693090; called by muse, mutect2, varscan2
- ABCC9 | c.134T>C p.L45S | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53983879; called by muse, mutect2, varscan2
- ABHD6 | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 99/377 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV55910153; called by muse, mutect2, varscan2
- AC013489.1 | c.458G>A p.C153Y | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51553288; called by muse, mutect2, varscan2
- ACACA | c.3148C>T p.L1050F | Missense Mutation (SNP) | VAF 61/282 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as rs547263573; called by muse, mutect2, varscan2
- ACSM5 | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 24/265 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759577702, COSV59374448; called by muse, mutect2
- ACTL7A | c.235G>T p.G79C | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61777215; called by muse, mutect2, varscan2
- ADAMTS15 | c.1130G>A p.C377Y | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54509329; called by muse, mutect2
- ADAMTS20 | c.4910G>A p.C1637Y | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67138108; called by muse, mutect2
- ADGRD1 | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as COSV55455770; called by muse, mutect2, varscan2
- ADNP | c.2196A>T p.L732F | Missense Mutation (SNP) | VAF 60/242 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.06); catalogued as COSV62426697; called by muse, mutect2, varscan2
- ADNP | c.2195T>A p.L732* | Nonsense Mutation (SNP) | VAF 60/242 reads (25%) | catalogued as COSV62426702; called by muse, mutect2, varscan2
- AGAP1 | c.1300A>G p.S434G | Missense Mutation (SNP) | VAF 55/208 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV58337820; called by muse, mutect2, varscan2
- AGBL5 | c.1266del p.E424Rfs*44 | Frame Shift Del (DEL) | VAF 57/253 reads (23%) | catalogued as rs747733044, COSV59935415; called by mutect2, pindel, varscan2
- AGO2 | c.1806del p.A603Pfs*92 | Frame Shift Del (DEL) | VAF 24/108 reads (22%) | catalogued as rs748399150; called by mutect2, pindel
- ALCAM | c.633G>T p.K211N | Missense Mutation (SNP) | VAF 190/801 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV60254034; called by muse, mutect2, varscan2
- ALDH6A1 | c.572T>C p.I191T | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV63247244; called by muse, mutect2
- AMDHD1 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 56/268 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1399291273, COSV57140208; called by muse, mutect2, varscan2
- AMY2A | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 69/662 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201672724; called by mutect2, varscan2
- ANKIB1 | c.2410G>A p.G804S | Missense Mutation (SNP) | VAF 87/321 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs939247560, COSV56060974; called by muse, mutect2, varscan2
- ARID1A | c.2402del p.G801Vfs*32 | Frame Shift Del (DEL) | VAF 38/173 reads (22%) | catalogued as COSV61388445; called by mutect2, pindel, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 82/323 reads (25%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID5B | c.71C>A p.A24D | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54428601; called by muse, varscan2
- ASB15 | c.422dup p.N141Kfs*2 | Frame Shift Ins (INS) | VAF 57/306 reads (19%) | catalogued as rs1423358635; called by mutect2, pindel, varscan2
- ATP11C | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 91/366 reads (25%) | catalogued as COSV59572801; called by muse, mutect2, varscan2
- ATP13A3 | c.2020G>A p.V674I | Missense Mutation (SNP) | VAF 115/442 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV55469068; called by muse, mutect2, varscan2
- BAP1 | c.1856G>A p.G619D | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV56239896; called by muse, mutect2, varscan2
- BOC | c.3061C>T p.R1021C | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as rs772484289, COSV56357030; called by muse, mutect2, varscan2
- BRWD3 | c.3728+1G>A p.X1243_splice | Splice Site (SNP) | VAF 68/259 reads (26%) | catalogued as COSV64752904; called by muse, mutect2, varscan2
- C1orf112 | c.756del p.F252Lfs*51 | Frame Shift Del (DEL) | VAF 28/228 reads (12%) | catalogued as rs1558068270; called by mutect2, pindel, varscan2
- CA5B | c.43C>G p.P15A | Missense Mutation (SNP) | VAF 118/475 reads (25%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.001); catalogued as COSV59417581; called by muse, mutect2, varscan2
- CARD11 | c.919C>T p.H307Y | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV67802003; called by muse, mutect2, varscan2
- CCDC141 | c.3678del p.A1228Hfs*19 | Frame Shift Del (DEL) | VAF 52/255 reads (20%) | catalogued as COSV55372055; called by mutect2, pindel, varscan2
- CCDC40 | c.3308G>A p.R1103Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as rs762363791, COSV56407173; called by muse, mutect2, varscan2
- CCDC65 | c.793del p.I265Yfs*8 | Frame Shift Del (DEL) | VAF 41/230 reads (18%) | catalogued as rs751586867; called by mutect2, pindel, varscan2
- CCDC9B | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 46/172 reads (27%) | catalogued as rs544274807, COSV66876167; called by muse, varscan2
- CCIN | c.585C>A p.D195E | Missense Mutation (SNP) | VAF 51/212 reads (24%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.968); catalogued as COSV58725484; called by muse, mutect2, varscan2
- CCT6A | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV51907420; called by muse, mutect2, varscan2
- CD163L1 | c.2803C>T p.R935C | Missense Mutation (SNP) | VAF 56/255 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as rs372569384; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 33/150 reads (22%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH1 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 112/456 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.316); catalogued as COSV55729284, COSV55739870; called by muse, mutect2, varscan2
- CEP350 | c.1244C>T p.T415I | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); catalogued as rs770476381, COSV62608980; called by muse, mutect2, varscan2
- CERS3 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 87/406 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV52573861; called by muse, mutect2, varscan2
- CHPT1 | c.825_827del p.I276del | In Frame Del (DEL) | VAF 58/287 reads (20%) | catalogued as rs748383370; called by pindel, varscan2
- CLPTM1 | c.646A>G p.T216A | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV61612887; called by muse, mutect2
- CNNM4 | c.2008C>A p.R670S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as rs558931421, COSV65662002; called by muse, mutect2, varscan2
- COL6A3 | c.7984G>A p.A2662T | Missense Mutation (SNP) | VAF 62/247 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.822); catalogued as rs749100905, COSV55099374; called by muse, mutect2, varscan2
- COPS5 | c.804T>A p.D268E | Missense Mutation (SNP) | VAF 54/202 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV63474844; called by muse, mutect2, varscan2
- COQ9 | c.629C>A p.P210H | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52647204; called by muse, mutect2, varscan2
- CPAMD8 | c.3845C>T p.A1282V (on ENST00000651564; = p.A1235V on NM_015692.5) | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV71597313; called by muse, mutect2
- CRLF2 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.363); catalogued as rs374874204, COSV67494236; called by muse, mutect2, varscan2
- CTNND1 | c.2773G>A p.D925N (on ENST00000399050 / NM_001085458.2; = p.D898N on NM_001331.3) | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as rs1204386527, COSV62382088; called by muse, mutect2, varscan2
- CWH43 | c.1616G>A p.G539D | Missense Mutation (SNP) | VAF 229/892 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as COSV56941009; called by muse, mutect2, varscan2
- CYP4F2 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 159/667 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs768028960, COSV50000701; called by muse, mutect2, varscan2
- DAB2IP | c.3484C>T p.Q1162* (on ENST00000408936; = p.Q1038* on NM_138709.2) | Nonsense Mutation (SNP) | VAF 114/441 reads (26%) | catalogued as COSV52267036; called by muse, mutect2, varscan2
- DBF4 | c.928C>A p.L310I | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV55998678; called by muse, mutect2, varscan2
- DCTD | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.622); catalogued as rs764782245, COSV63866968; called by muse, mutect2, varscan2
- DEK | c.863G>C p.S288T | Missense Mutation (SNP) | VAF 69/246 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV55236368; called by muse, mutect2, varscan2
- DMXL2 | c.326dup p.L109Ffs*15 | Frame Shift Ins (INS) | VAF 38/172 reads (22%) | catalogued as rs752363479; called by mutect2, varscan2
- DNAH9 | c.1780G>T p.E594* | Nonsense Mutation (SNP) | VAF 56/266 reads (21%) | catalogued as COSV52345533, COSV52373663; called by muse, mutect2, varscan2
- DNER | c.1855+1G>A p.X619_splice | Splice Site (SNP) | VAF 88/399 reads (22%) | catalogued as rs760706711, COSV59174891, COSV99080080; called by muse, mutect2, varscan2
- DST | c.22006C>T p.P7336S (on ENST00000361203 / NM_001374722.1; = p.P5046S on NM_015548.5) | Missense Mutation (SNP) | VAF 60/227 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as COSV55036522; called by muse, mutect2, varscan2
- EIF2S1 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.114); catalogued as rs1277999711, COSV53600517; called by muse, mutect2
- ELN | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.24); catalogued as COSV52714900; called by muse, mutect2, varscan2
- EPS15 | c.74A>C p.Q25P | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65532609; called by muse, mutect2, varscan2
- ERVFRD-1 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs768463887, COSV65369528; called by muse, mutect2, varscan2
- ESRRG | c.215T>C p.M72T | Missense Mutation (SNP) | VAF 67/399 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.033); catalogued as COSV63178290; called by muse, mutect2, varscan2
- FAM120A | c.2101G>A p.A701T | Missense Mutation (SNP) | VAF 69/307 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.113); catalogued as COSV52909967; called by muse, mutect2, varscan2
- FAM135B | c.2318C>T p.A773V | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52749817; called by muse, mutect2, varscan2
- FAT3 | c.12925G>A p.A4309T | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV53102655; called by muse, mutect2, varscan2
- FIG4 | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs139235893; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMO4 | c.1321A>G p.I441V | Missense Mutation (SNP) | VAF 70/465 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.277); catalogued as COSV63001862; called by muse, mutect2, varscan2
- FOSB | c.860A>G p.Q287R | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV62279235; called by muse, mutect2, varscan2
- FRMPD3 | c.1355A>G p.Q452R | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV99345350; called by muse, mutect2
- FRMPD4 | c.2402G>A p.R801H | Missense Mutation (SNP) | VAF 169/646 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772679523, COSV66222119; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRP | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs202158019; called by muse, mutect2, varscan2
- GALNT6 | c.1663C>T p.H555Y | Missense Mutation (SNP) | VAF 61/226 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.876); catalogued as COSV62543252; called by muse, mutect2, varscan2
- GAS2L1 | c.1711A>G p.S571G | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV53331768; called by muse, mutect2, varscan2
- GATA1 | c.496C>A p.P166T | Missense Mutation (SNP) | VAF 188/741 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV64963440; called by muse, mutect2, varscan2
- GON4L | c.4615C>T p.Q1539* | Nonsense Mutation (SNP) | VAF 16/77 reads (21%) | catalogued as COSV55202559; called by muse, mutect2
- GPA33 | c.767T>C p.I256T | Missense Mutation (SNP) | VAF 51/374 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV63302107; called by muse, mutect2, varscan2
- GPLD1 | c.1717G>T p.G573C | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57760612; called by muse, mutect2
- GPR132 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs769671782, COSV61678317; called by muse, varscan2
- GRM1 | c.284T>C p.L95P | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51289195; called by muse, mutect2, varscan2
- GUCY1A1 | c.796C>A p.L266M | Missense Mutation (SNP) | VAF 71/308 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.305); catalogued as COSV56655798; called by muse, mutect2, varscan2
- GULP1 | c.158T>C p.L53P | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63073361; called by muse, mutect2, varscan2
- HAO2 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.466); catalogued as rs763195884, COSV58039408; called by muse, mutect2, varscan2
- HELLS | c.461del p.N154Ifs*29 | Frame Shift Del (DEL) | VAF 34/136 reads (25%) | catalogued as rs775038246; called by mutect2, varscan2
- HERC2 | c.511G>T p.G171C | Missense Mutation (SNP) | VAF 74/248 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as COSV55346571; called by muse, mutect2, varscan2
- HHIPL2 | c.1817del p.P606Qfs*11 | Frame Shift Del (DEL) | VAF 51/368 reads (14%) | catalogued as rs777317485; called by mutect2, pindel, varscan2
- HSPBAP1 | c.419C>T p.T140I | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as rs1249723454, COSV60243657; called by muse, mutect2, varscan2
- ICE2 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs912762907, COSV55030349; called by muse, mutect2, varscan2
- IFITM2 | c.346A>G p.M116V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs530463865, COSV60249917; called by muse, mutect2
- IGFBP7 | c.497C>A p.P166H | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55276204; called by muse, mutect2, varscan2
- IGSF9B | c.2070G>A p.M690I | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as COSV58066424; called by muse, mutect2
- IL12RB1 | c.1837C>A p.L613M | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.564); catalogued as COSV74045662; called by muse, mutect2, varscan2
- IL5RA | c.495G>T p.E165D | Missense Mutation (SNP) | VAF 56/235 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV56521257; called by muse, mutect2, varscan2
- INKA1 | c.233G>T p.R78M | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV58526892; called by muse, mutect2
- IQCC | c.1183C>A p.L395I | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.476); catalogued as COSV52210966; called by muse, mutect2, varscan2
- IQCH | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 114/499 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs746235029, COSV60058542; called by muse, mutect2, varscan2
- KCNA2 | c.239G>T p.R80L | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60371302; called by muse, mutect2, varscan2
- KCND2 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as rs756823168, COSV58586030; called by muse, mutect2, varscan2
- KIAA1217 | c.2098G>A p.V700M | Missense Mutation (SNP) | VAF 53/216 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs142233164; called by muse, mutect2, varscan2
- KIFAP3 | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 47/315 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63034171; called by muse, mutect2, varscan2
- KMT2D | c.10658G>A p.G3553D | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56459740; called by muse, mutect2, varscan2
- KNOP1 | c.957del p.G320Afs*8 | Frame Shift Del (DEL) | VAF 18/66 reads (27%) | catalogued as rs759734033, COSV54927684; called by mutect2, varscan2
- KRTAP10-5 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 24/410 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59949930, COSV59977939; called by muse, mutect2
- KRTAP4-12 | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV67458241; called by muse, mutect2, varscan2
- LAMA2 | c.5432T>C p.M1811T | Missense Mutation (SNP) | VAF 45/261 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as COSV70354194; called by muse, mutect2, varscan2
- LCA5L | c.467del p.N156Mfs*3 | Frame Shift Del (DEL) | VAF 55/246 reads (22%) | catalogued as rs747213855; called by mutect2, pindel, varscan2
- LGMN | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.226); catalogued as rs762575227, COSV58403864; called by muse, mutect2, varscan2
- LIPE | c.1799C>A p.P600H | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54925130; called by muse, mutect2, varscan2
- LRP1 | c.8381G>A p.C2794Y | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54524082; called by muse, mutect2, varscan2
- LRP1 | c.9824C>A p.P3275H | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); catalogued as COSV54524093; called by muse, mutect2
- LRRC6 | c.1025G>C p.R342P | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV51539661, COSV51546987; called by muse, mutect2, varscan2
- LRRN1 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 99/404 reads (25%) | catalogued as COSV60015846; called by muse, mutect2, varscan2
- LYN | c.164G>T p.R55M | Missense Mutation (SNP) | VAF 59/269 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV72923687; called by muse, mutect2, varscan2
- LYST | c.8769G>A p.W2923* | Nonsense Mutation (SNP) | VAF 22/348 reads (6%) | catalogued as COSV67704589; called by muse, mutect2
- MAGIX | c.510C>A p.V170= | Splice Region (SNP) | VAF 10/26 reads (38%) | catalogued as rs1557097496, COSV100891872, COSV66256555; called by muse, mutect2, varscan2
- MAP11 | c.1172C>T p.T391M | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs747313913, COSV57588053; called by muse, mutect2, varscan2
- MASP1 | c.1756G>A p.V586I | Missense Mutation (SNP) | VAF 57/294 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); catalogued as rs144026900, COSV61830415; called by muse, mutect2, varscan2
- MAST4 | c.7735G>T p.G2579C (on ENST00000403625 / NM_001164664.2; = p.G2390C on NM_015183.3) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.322); catalogued as COSV55139825; called by muse, mutect2
- MBD6 | c.2200del p.Q734Nfs*18 | Frame Shift Del (DEL) | VAF 15/84 reads (18%) | catalogued as rs749738168; called by mutect2, pindel, varscan2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 21/59 reads (36%) | catalogued as rs746267361; called by mutect2, varscan2
- MCOLN3 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs371225249; called by muse, mutect2, varscan2
- MDN1 | c.14265G>T p.E4755D | Missense Mutation (SNP) | VAF 79/311 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV65529222; called by muse, mutect2, varscan2
- MFSD14A | c.1101G>T p.Q367H | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV64515269; called by muse, mutect2, varscan2
- MMS22L | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 192/723 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.134); catalogued as COSV51525825; called by muse, mutect2, varscan2
- MOGS | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs752641712, COSV51968934; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MOV10 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs150955367; called by muse, mutect2, varscan2
- MRPL37 | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as rs184402036, COSV60322548; called by muse, mutect2, varscan2
- MUC5B | c.9598G>A p.A3200T | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs867241477, COSV71594927; called by muse, mutect2, varscan2
- MYH14 | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs727505282, COSV51813870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYOM1 | c.3034G>A p.A1012T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.392); catalogued as COSV55288809; called by muse, mutect2
- NAV3 | c.4211G>C p.G1404A | Missense Mutation (SNP) | VAF 84/399 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV57090991, COSV57108456; called by muse, mutect2, varscan2
- NAV3 | c.6631G>A p.V2211I (on ENST00000397909 / NM_001024383.2; = p.V2189I on NM_014903.6) | Missense Mutation (SNP) | VAF 51/232 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV57108469; called by muse, mutect2, varscan2
- NDST2 | c.479A>G p.Y160C | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55217482; called by muse, mutect2, varscan2
- NECTIN4 | c.665C>T p.T222I | Missense Mutation (SNP) | VAF 39/227 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV63513859; called by muse, mutect2, varscan2
- NEXN | c.761T>C p.L254P | Missense Mutation (SNP) | VAF 159/556 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as COSV53944452; called by muse, mutect2, varscan2
- NHSL2 | c.620G>T p.R207L (on ENST00000510661; = p.R573L on NM_001013627.2) | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV101030219, COSV65454793; called by muse, mutect2, varscan2
- NKAP | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 91/401 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57631113; called by muse, mutect2, varscan2
- NOL4 | c.1841C>T p.A614V | Missense Mutation (SNP) | VAF 55/245 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52359845; called by muse, mutect2, varscan2
- NOTCH4 | c.3917del p.P1306Qfs*3 | Frame Shift Del (DEL) | VAF 26/94 reads (28%) | catalogued as rs1263727065; called by mutect2, pindel, varscan2
- NR5A2 | c.656C>T p.A219V (on ENST00000367362 / NM_205860.3; = p.A173V on NM_003822.5) | Missense Mutation (SNP) | VAF 89/511 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV52656870; called by muse, mutect2, varscan2
- NSD1 | c.3430G>A p.E1144K | Missense Mutation (SNP) | VAF 103/389 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.874); catalogued as COSV61783681; called by muse, mutect2, varscan2
- NVL | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 116/658 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs748891622, COSV55875748; called by muse, mutect2, varscan2
- OGDHL | c.1327C>A p.R443S | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65104348; called by muse, mutect2, varscan2
- OLFM4 | c.254G>A p.C85Y | Missense Mutation (SNP) | VAF 114/416 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54579124, COSV54579998; called by muse, mutect2, varscan2
- OLFML2A | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56585415; called by muse, mutect2, varscan2
- OR10J3 | c.448C>A p.L150M | Missense Mutation (SNP) | VAF 132/664 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.852); catalogued as COSV59955523; called by muse, mutect2, varscan2
- OR12D3 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 110/395 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs202129682; called by muse, mutect2, varscan2
- OR2B2 | c.25C>A p.P9T | Missense Mutation (SNP) | VAF 106/433 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as COSV57580617; called by muse, mutect2, varscan2
- OR2S2 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 98/356 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV59529838; called by muse, mutect2, varscan2
- OR2T3 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 52/1062 reads (5%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs759032581, COSV100613033, COSV62081664; called by muse, mutect2
- OR4D5 | c.189G>T p.L63F | Missense Mutation (SNP) | VAF 126/448 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58309195; called by muse, mutect2, varscan2
- OR52L1 | c.344G>T p.C115F | Missense Mutation (SNP) | VAF 72/280 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372998184; called by muse, mutect2, varscan2
- OR6C75 | c.599del p.L200* | Frame Shift Del (DEL) | VAF 90/384 reads (23%) | catalogued as rs746200712; called by mutect2, varscan2
- PCDHB15 | c.2219G>A p.S740N | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.039); catalogued as COSV51349519; called by muse, mutect2, varscan2
- PCDHGA11 | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as COSV53895395; called by muse, mutect2, varscan2
- PCGF1 | c.319A>G p.I107V | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.279); catalogued as COSV52044359; called by muse, mutect2, varscan2
- PCNT | c.8632T>A p.S2878T | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.071); catalogued as COSV64032567; called by muse, mutect2, varscan2
- PDZD2 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 35/130 reads (27%) | catalogued as rs764974350, COSV56865646; called by muse, mutect2, varscan2
- PENK | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 75/263 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs367716870; called by muse, mutect2, varscan2
- PHC3 | c.659G>T p.S220I (on ENST00000494943 / NM_001308116.2; = p.S232I on NM_024947.4) | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV71949290; called by muse, mutect2, varscan2
- PHF10 | c.1448del p.P483Qfs*? | Frame Shift Del (DEL) | VAF 27/105 reads (26%) | catalogued as rs754137375; called by mutect2, pindel, varscan2
- PHOX2B | c.410T>C p.L137P | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD130373, COSV56931353; called by muse, mutect2, varscan2
- PIK3C2A | c.4663A>G p.T1555A | Missense Mutation (SNP) | VAF 16/321 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV56404663; called by muse, mutect2
- PIK3C3 | c.2429G>A p.R810Q | Missense Mutation (SNP) | VAF 66/277 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs893280651, COSV56283786; called by muse, mutect2, varscan2
- PIP4K2A | c.941del p.P314Qfs*8 | Frame Shift Del (DEL) | VAF 22/216 reads (10%) | catalogued as rs755454854; called by mutect2, pindel, varscan2
- PIP5K1B | c.1487C>T p.T496I | Missense Mutation (SNP) | VAF 114/478 reads (24%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV55256644; called by muse, mutect2, varscan2
- PISD | c.1205T>C p.F402S (on ENST00000439502 / NM_001326412.1; = p.F368S on NM_014338.3) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as rs768069104, COSV56718722; called by muse, mutect2
- PKD1L1 | c.2981C>T p.P994L | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV56960727; called by muse, mutect2, varscan2
- PKHD1L1 | c.9360C>A p.N3120K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as rs1433034766, COSV65751410; called by muse, mutect2, varscan2
- PLCZ1 | c.1040T>C p.L347P | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.346); catalogued as COSV56857954; called by muse, mutect2, varscan2
- PLEK | c.170G>A p.S57N | Missense Mutation (SNP) | VAF 33/390 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV52253692; called by muse, mutect2
- PLK1 | c.1022C>T p.T341I | Missense Mutation (SNP) | VAF 107/433 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV55624142; called by muse, mutect2, varscan2
- PMS2 | c.994G>A p.V332I | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.162); catalogued as rs1236095389, COSV56220915; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRMT2 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 63/207 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.6); catalogued as rs899553433, COSV52457696; called by muse, mutect2, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 54/198 reads (27%) | catalogued as rs753236928; called by mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 270/622 reads (43%) | catalogued as rs146650273; called by pindel, varscan2
- PTOV1 | c.642C>A p.F214L | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV55588644, COSV55590338; called by muse, mutect2, varscan2
- PTPN12 | c.842A>T p.E281V | Missense Mutation (SNP) | VAF 121/479 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50370057; called by muse, mutect2, varscan2
- PTPRG | c.4153del p.M1385* | Frame Shift Del (DEL) | VAF 107/502 reads (21%) | catalogued as rs747014614; called by mutect2, pindel, varscan2
- PUM1 | c.2894T>C p.V965A | Missense Mutation (SNP) | VAF 51/226 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV57090556; called by muse, mutect2, varscan2
- QRFP | c.368G>A p.S123N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.08); catalogued as rs1247644614, COSV58064871; called by muse, mutect2
- RAB11FIP1 | c.2943G>T p.Q981H | Missense Mutation (SNP) | VAF 102/383 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.125); catalogued as COSV54763314; called by muse, mutect2, varscan2
- RALB | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs141928830; called by muse, varscan2
- RBM14 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV59560504; called by muse, mutect2
- REC8 | c.1448A>G p.H483R | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV61018154; called by muse, mutect2, varscan2
- RGS6 | c.698T>A p.V233E | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.12); catalogued as COSV59596576; called by muse, mutect2
- RNF216 | c.341A>G p.N114S (on ENST00000425013 / NM_207116.3; = p.N171S on NM_207111.4) | Missense Mutation (SNP) | VAF 122/455 reads (27%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as rs1299880205, COSV66292506; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 58/162 reads (36%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROS1 | c.4318C>T p.P1440S | Missense Mutation (SNP) | VAF 87/366 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs867084033, COSV63859938; called by muse, mutect2, varscan2
- RPL7A | c.281A>G p.Q94R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV59299828; called by muse, mutect2, varscan2
- RPLP0 | c.409T>C p.F137L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV56114031; called by muse, mutect2, varscan2
- RPTN | c.627dup p.V210Sfs*11 | Frame Shift Ins (INS) | VAF 321/2334 reads (14%) | catalogued as rs750891148; called by mutect2, pindel, varscan2
- RYR2 | c.4406T>A p.L1469Q | Missense Mutation (SNP) | VAF 74/437 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV63710130; called by muse, mutect2, varscan2
- RYR2 | c.13327G>A p.E4443K | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as rs1409192667, COSV63710137; called by muse, mutect2, varscan2
- SAC3D1 | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs775031585, COSV57248406; called by muse, mutect2, varscan2
- SCN5A | c.4340A>T p.Y1447F (on ENST00000333535 / NM_198056.3; = p.Y1446F on NM_000335.5) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61139063; called by muse, mutect2, varscan2
- SEC14L4 | c.859G>T p.G287C | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55401350; called by muse, mutect2, varscan2
- SETBP1 | c.1898C>T p.A633V | Missense Mutation (SNP) | VAF 86/375 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.111); catalogued as COSV56335156; called by muse, mutect2, varscan2
- SHPRH | c.4976A>G p.K1659R | Missense Mutation (SNP) | VAF 51/233 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.989); catalogued as COSV51616447; called by muse, mutect2, varscan2
- SLC10A5 | c.649G>T p.G217* | Nonsense Mutation (SNP) | VAF 107/443 reads (24%) | catalogued as COSV72828470; called by muse, mutect2, varscan2
- SLC17A5 | c.699del p.F233Lfs*15 | Frame Shift Del (DEL) | VAF 32/126 reads (25%) | catalogued as rs779548058; called by mutect2, pindel, varscan2
- SLC17A8 | c.1208T>C p.L403S | Missense Mutation (SNP) | VAF 118/478 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV60126333; called by muse, mutect2, varscan2
- SLC22A7 | c.1247C>T p.A416V (on ENST00000372585 / NM_153320.2; = p.A414V on NM_006672.3) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as rs1468271662, COSV51483970, COSV51485833; called by muse, mutect2, varscan2
- SLC25A24 | c.570del p.K190Nfs*29 | Frame Shift Del (DEL) | VAF 70/293 reads (24%) | catalogued as rs763273320; called by mutect2, varscan2
- SLC44A3 | c.1722del p.F574Lfs*4 (on ENST00000271227 / NM_001114106.3; = p.F526Lfs*4 on NM_152369.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 122/564 reads (22%) | catalogued as rs752543591, COSV54732637; called by mutect2, pindel, varscan2
- SPOCK3 | c.1280A>G p.D427G | Missense Mutation (SNP) | VAF 92/308 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.243); catalogued as rs753557766, COSV62717220; called by muse, mutect2, varscan2
- ST3GAL3 | c.936+1dup | Frame Shift Ins (INS) | VAF 21/133 reads (16%) | catalogued as rs1387140766; called by mutect2, varscan2
- STAC | c.310G>T p.G104C | Missense Mutation (SNP) | VAF 81/322 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as COSV56217205; called by muse, mutect2, varscan2
- SUOX | c.1067C>A p.P356H | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56269952; called by muse, mutect2, varscan2
- SURF1 | c.591T>C p.I197= | Splice Region (SNP) | VAF 6/40 reads (15%) | catalogued as COSV59299832; called by muse, mutect2
- SVIL | c.6547G>A p.E2183K (on ENST00000355867 / NM_021738.3; = p.E1757K on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/199 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs758477266, COSV63442718; called by muse, mutect2, varscan2
- TAF1L | c.422A>G p.D141G | Missense Mutation (SNP) | VAF 84/400 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54267941; called by muse, mutect2, varscan2
- TAS1R2 | c.920A>T p.D307V | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64746905; called by muse, mutect2, varscan2
- TENM1 | c.6242G>A p.S2081N | Missense Mutation (SNP) | VAF 106/401 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.632); catalogued as rs750992646, COSV64441326; called by muse, mutect2, varscan2
- TENT2 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 78/317 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57135069, COSV57138191; called by muse, mutect2, varscan2
- TFCP2 | c.491G>T p.R164M | Missense Mutation (SNP) | VAF 20/388 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as COSV99227373; called by muse, mutect2
- THSD7B | c.3906del p.C1303Afs*59 (on ENST00000272643; = p.C1301Afs*59 on NM_001316349.2) | Frame Shift Del (DEL) | VAF 69/326 reads (21%) | catalogued as COSV55687791; called by mutect2, pindel, varscan2
- TIMD4 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 190/817 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs753614328, COSV50856004; called by muse, mutect2, varscan2
- TINF2 | c.550A>G p.T184A | Missense Mutation (SNP) | VAF 217/882 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as COSV57470383; called by muse, mutect2, varscan2
- TJP1 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 114/520 reads (22%) | catalogued as COSV62039118; called by muse, mutect2, varscan2
- TKT | c.1648C>T p.R550C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs782746915, COSV56246916; called by muse, mutect2, varscan2
- TMEM41A | c.467dup p.L158Ifs*40 | Frame Shift Ins (INS) | VAF 71/296 reads (24%) | catalogued as rs758476632; called by mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 62/299 reads (21%) | catalogued as rs749773249; called by mutect2, varscan2
- TNKS2 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 30/291 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.03); catalogued as COSV65415441, COSV65416788; called by muse, mutect2
- TOGARAM1 | c.3830G>A p.G1277E | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63894669; called by muse, mutect2, varscan2
- TRMT10C | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 42/340 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as COSV59306730; called by muse, mutect2, varscan2
- TTC13 | c.1721G>T p.R574M | Missense Mutation (SNP) | VAF 110/678 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64169812; called by muse, mutect2, varscan2
- UBN2 | c.888del p.V297Ffs*10 | Frame Shift Del (DEL) | VAF 69/275 reads (25%) | catalogued as rs149079838; called by mutect2, pindel, varscan2
- UROC1 | c.1328C>G p.S443C | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52029620, COSV52038435; called by muse, mutect2, varscan2
- VAT1 | c.514A>G p.N172D | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs751509304, COSV63040439; called by muse, mutect2
- VNN2 | c.800C>T p.T267I | Missense Mutation (SNP) | VAF 167/657 reads (25%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV100426727, COSV58474003; called by muse, mutect2, varscan2
- VWF | c.6922G>A p.E2308K | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV54632525; called by muse, mutect2, varscan2
- WHAMM | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs770096808, COSV54499397; called by muse, mutect2
- WRNIP1 | c.1130T>C p.L377P | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66356361; called by muse, mutect2, varscan2
- ZBTB18 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 50/310 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.166); catalogued as rs140203623; called by muse, mutect2, varscan2
- ZBTB41 | c.714del p.K238Nfs*4 | Frame Shift Del (DEL) | VAF 70/435 reads (16%) | catalogued as COSV100962778; called by mutect2, pindel, varscan2
- ZC3H10 | c.137T>C p.L46S | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV57769850; called by muse, mutect2, varscan2
- ZC3H12A | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs1192005707, COSV66104505; called by muse, mutect2, varscan2
- ZNF230 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as COSV71273674; called by muse, mutect2, varscan2
- ZNF322 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); catalogued as COSV70652238; called by mutect2, varscan2
- ZNF43 | c.752del p.N251Ifs*28 | Frame Shift Del (DEL) | VAF 84/368 reads (23%) | catalogued as rs753886536; called by mutect2, varscan2
- ZNF470 | c.584T>C p.M195T | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs771585472, COSV57970491; called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.316del p.T106Hfs*5 | Frame Shift Del (DEL) | VAF 48/213 reads (23%) | catalogued as COSV58672905; called by mutect2, pindel, varscan2
- ZNF804B | c.1809G>T p.K603N | Missense Mutation (SNP) | VAF 113/412 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as COSV60850928; called by muse, mutect2, varscan2
- ZSCAN21 | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52852245; called by muse, mutect2, varscan2
- ZSCAN29 | c.364A>C p.T122P | Missense Mutation (SNP) | VAF 57/245 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.095); catalogued as COSV53021078; called by muse, mutect2, varscan2
- AK7 | c.687del p.F229Lfs*21 | Frame Shift Del (DEL) | VAF 38/152 reads (25%) | called by mutect2, pindel, varscan2
- ASH1L | c.3665del p.K1222Rfs*11 | Frame Shift Del (DEL) | VAF 184/1110 reads (17%) | called by mutect2, varscan2
- ASXL2 | c.69del p.K23Nfs*7 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | called by mutect2, pindel, varscan2
- BTBD16 | c.906del p.F302Lfs*15 | Frame Shift Del (DEL) | VAF 137/562 reads (24%) | called by mutect2, pindel, varscan2
- CADM2 | c.290_291dup p.D98Lfs*45 (on ENST00000407528 / NM_001167674.2; = p.D100Lfs*45 on NM_153184.4) | Frame Shift Ins (INS) | VAF 20/93 reads (22%) | called by mutect2, varscan2
- CLASRP | c.284del p.P95Lfs*81 | Frame Shift Del (DEL) | VAF 51/249 reads (20%) | called by mutect2, pindel, varscan2
- CPEB2 | c.2941del p.C981Vfs*31 | Frame Shift Del (DEL) | VAF 92/368 reads (25%) | called by mutect2, varscan2
- CREBBP | c.1103dup p.R369Efs*58 | Frame Shift Ins (INS) | VAF 59/221 reads (27%) | called by mutect2, pindel, varscan2
- DCAF15 | c.851del p.P284Lfs*79 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | called by mutect2, varscan2
- DNPEP | c.1413_1415del p.F472del | In Frame Del (DEL) | VAF 34/188 reads (18%) | called by pindel, varscan2
- EIF2AK4 | c.4728+2dup p.X1576_splice | Splice Site (INS) | VAF 56/257 reads (22%) | called by mutect2, pindel, varscan2
- FUBP3 | c.1184del p.P395Lfs*27 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel
- GRIN3A | c.1757del p.K586Rfs*2 | Frame Shift Del (DEL) | VAF 60/280 reads (21%) | called by mutect2, pindel, varscan2
- GUCY1B1 | c.1823del p.N608Ifs*19 | Frame Shift Del (DEL) | VAF 29/120 reads (24%) | called by mutect2, pindel, varscan2
- IARS2 | c.2842_2845del p.E948* | Frame Shift Del (DEL) | VAF 26/169 reads (15%) | called by mutect2, pindel, varscan2
- INPPL1 | c.3201del p.S1068Afs*63 | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | called by mutect2, varscan2
- JHY | c.841del p.R281Efs*15 | Frame Shift Del (DEL) | VAF 86/418 reads (21%) | called by mutect2, pindel, varscan2
- KIAA0895L | c.45del p.S16Afs*13 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by mutect2, varscan2
- LIG3 | c.469del p.I157Sfs*21 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | called by mutect2, varscan2
- NCAM1 | c.592del p.E198Rfs*11 | Frame Shift Del (DEL) | VAF 167/773 reads (22%) | called by mutect2, pindel, varscan2
- NEK7 | c.192dup p.V65Sfs*5 | Frame Shift Ins (INS) | VAF 110/652 reads (17%) | called by mutect2, varscan2
- PHF1 | c.16del p.R6Gfs*2 | Frame Shift Del (DEL) | VAF 16/79 reads (20%) | called by mutect2, pindel, varscan2
- PLEKHA5 | c.929del p.N310Tfs*4 | Frame Shift Del (DEL) | VAF 53/219 reads (24%) | called by mutect2, pindel, varscan2
- POGK | c.1271del p.P424Rfs*18 | Frame Shift Del (DEL) | VAF 40/191 reads (21%) | called by mutect2, pindel, varscan2
- POLR1F | c.932del p.K311Rfs*15 | Frame Shift Del (DEL) | VAF 204/842 reads (24%) | called by mutect2, varscan2
- PXDN | c.2592del p.N865Mfs*25 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, varscan2
- SENP6 | c.206dup p.L70Vfs*6 | Frame Shift Ins (INS) | VAF 41/214 reads (19%) | called by mutect2, pindel, varscan2
- SLC44A5 | c.1230dup p.H411Afs*5 | Frame Shift Ins (INS) | VAF 68/320 reads (21%) | called by pindel, varscan2
- SPTAN1 | c.6232_6234del p.K2078del | In Frame Del (DEL) | VAF 24/106 reads (23%) | called by pindel, varscan2
- TEAD1 | c.848del p.N283Mfs*6 | Frame Shift Del (DEL) | VAF 97/431 reads (23%) | called by mutect2, pindel, varscan2
- TET3 | c.4851del p.S1618Afs*5 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | called by mutect2, pindel
- TFDP2 | c.606del p.E203Kfs*20 (on ENST00000489671 / NM_001178139.2; = p.E143Kfs*20 on NM_006286.5) | Frame Shift Del (DEL) | VAF 44/182 reads (24%) | called by mutect2, varscan2
- UBE2Q1 | c.1235del p.N412Tfs*117 | Frame Shift Del (DEL) | VAF 93/628 reads (15%) | called by mutect2, varscan2
- USP9X | c.82del p.L28Sfs*51 | Frame Shift Del (DEL) | VAF 36/159 reads (23%) | called by mutect2, pindel, varscan2
- WNT1 | c.580C>A p.L194M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- ZNF212 | c.403del p.E135Rfs*35 | Frame Shift Del (DEL) | VAF 24/159 reads (15%) | called by mutect2, pindel, varscan2
- ADAMTS19 | c.732C>A p.T244= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV50784058; called by muse, mutect2, varscan2
- ADAMTSL3 | c.987C>T p.S329= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as rs140676489, COSV54439420; called by muse, mutect2, varscan2
- ADGRL3 | c.414T>C p.P138= (on ENST00000506720 / NM_001322402.2; = p.P70= on NM_015236.6) | Silent (SNP) | VAF 29/135 reads (21%) | catalogued as rs763145696, COSV72272900; called by muse, mutect2, varscan2
- AMBRA1 | c.294A>G p.P98= | Silent (SNP) | VAF 126/597 reads (21%) | catalogued as rs781173410, COSV54061602; called by muse, mutect2, varscan2
- ANKDD1A | c.1194G>A p.L398= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV63088963; called by muse, mutect2, varscan2
- ANKIB1 | c.1647T>C p.L549= | Silent (SNP) | VAF 33/135 reads (24%) | catalogued as COSV56065500; called by muse, mutect2, varscan2
- ANKK1 | c.862C>T p.L288= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV58274022; called by muse, mutect2, varscan2
- AP3D1 | c.3118C>T p.L1040= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs1199952671, COSV61432333; called by muse, mutect2, varscan2
- ARSH | c.1485G>T p.L495= | Silent (SNP) | VAF 75/274 reads (27%) | catalogued as COSV66963748, COSV66963796; called by muse, mutect2, varscan2
- ASH1L | c.7653A>G p.S2551= (on ENST00000368346 / NM_001366177.2; = p.S2546= on NM_018489.3) | Silent (SNP) | VAF 31/1001 reads (3%) | catalogued as COSV64212994; called by muse, mutect2
- ATP5F1A | c.1392C>T p.G464= | Silent (SNP) | VAF 87/295 reads (29%) | catalogued as rs143320751; called by muse, mutect2, varscan2
- BCL11A | c.2007C>A p.P669= (on ENST00000335712 / NM_001365609.1; = p.P703= on NM_018014.4) | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV59636109; called by mutect2, varscan2
- BCO1 | c.1539C>A p.L513= | Silent (SNP) | VAF 68/226 reads (30%) | catalogued as rs368392677; called by muse, mutect2, varscan2
- BSN | c.10158G>A p.A3386= | Silent (SNP) | VAF 25/125 reads (20%) | catalogued as rs770141757, COSV56526158; called by muse, mutect2, varscan2
- CCZ1B | c.417G>A p.R139= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as rs199643615, COSV57439259; called by muse, mutect2, varscan2
- CDH26 | c.1068C>T p.V356= | Silent (SNP) | VAF 37/208 reads (18%) | catalogued as COSV54853702; called by muse, mutect2, varscan2
- CHRNG | c.768C>A p.S256= | Silent (SNP) | VAF 55/242 reads (23%) | catalogued as rs1275665308, COSV67315621, COSV67315972; called by muse, mutect2, varscan2
- CLK2 | c.906C>T p.D302= (on ENST00000368361 / NM_001294339.2; = p.D301= on NM_003993.4) | Silent (SNP) | VAF 42/287 reads (15%) | catalogued as COSV56946552, COSV56947219; called by muse, mutect2, varscan2
- CNGB1 | c.1080A>G p.E360= | Silent (SNP) | VAF 45/221 reads (20%) | catalogued as COSV51906324; called by muse, mutect2, varscan2
- COL22A1 | c.921G>A p.K307= | Silent (SNP) | VAF 54/204 reads (26%) | catalogued as COSV57337696; called by muse, mutect2, varscan2
- COL9A2 | c.843C>T p.D281= | Silent (SNP) | VAF 51/240 reads (21%) | catalogued as rs140305893, COSV65607455; ClinVar: likely benign; called by muse, mutect2, varscan2
- DCLRE1B | c.753G>A p.T251= | Silent (SNP) | VAF 66/257 reads (26%) | catalogued as rs574323645, COSV65813125; called by muse, mutect2, varscan2
- DDI1 | c.1068G>A p.T356= | Silent (SNP) | VAF 61/207 reads (29%) | catalogued as rs760519987, COSV56391820; called by muse, mutect2, varscan2
- DSP | c.3819C>T p.N1273= | Silent (SNP) | VAF 60/280 reads (21%) | catalogued as rs1390665527, COSV65795373; ClinVar: likely benign; called by muse, mutect2, varscan2
- EPHB2 | c.591C>T p.C197= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV65866095; called by muse, mutect2, varscan2
- ESAM | c.1107C>T p.G369= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV54036584; called by muse, mutect2
- F2R | c.900C>T p.S300= | Silent (SNP) | VAF 46/195 reads (24%) | catalogued as COSV59930000; called by muse, mutect2, varscan2
- FAM20B | c.405G>T p.G135= | Silent (SNP) | VAF 60/335 reads (18%) | catalogued as COSV55382296; called by muse, mutect2, varscan2
- FBXO16 | c.348C>T p.C116= | Silent (SNP) | VAF 79/262 reads (30%) | catalogued as COSV60777520; called by muse, mutect2, varscan2
- FSHR | c.1683C>T p.I561= | Silent (SNP) | VAF 60/204 reads (29%) | catalogued as rs757713421, COSV58623930; called by muse, mutect2, varscan2
- GLUD2 | c.774A>G p.K258= | Silent (SNP) | VAF 16/220 reads (7%) | catalogued as COSV60152941, COSV60153378; called by muse, mutect2
- GTPBP2 | c.858C>T p.L286= | Silent (SNP) | VAF 54/185 reads (29%) | catalogued as rs139289282; called by muse, mutect2, varscan2
- HMCN1 | c.15228T>G p.G5076= | Silent (SNP) | VAF 53/360 reads (15%) | catalogued as COSV54935665; called by muse, mutect2, varscan2
- HUS1B | c.99C>A p.R33= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV57862165, COSV57871245; called by muse, mutect2, varscan2
- HYKK | c.213T>C p.A71= | Silent (SNP) | VAF 76/341 reads (22%) | catalogued as COSV64762726; called by muse, mutect2, varscan2
- KCND1 | c.93G>A p.P31= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs368004864, COSV54415720, COSV99501798, COSV99502109; called by muse, varscan2
- KIAA1614 | c.741C>T p.G247= | Silent (SNP) | VAF 42/183 reads (23%) | catalogued as rs374668814; called by muse, mutect2, varscan2
- KIFBP | c.1683T>C p.D561= | Silent (SNP) | VAF 104/398 reads (26%) | catalogued as COSV62832393; called by muse, mutect2
- KMT2C | c.7821C>T p.P2607= | Silent (SNP) | VAF 14/200 reads (7%) | catalogued as rs1465769747, COSV51494984; called by muse, mutect2
- LDLRAD4 | c.492C>T p.H164= | Silent (SNP) | VAF 39/158 reads (25%) | catalogued as rs771512980, COSV63342460; called by muse, mutect2, varscan2
- LELP1 | c.279C>A p.P93= | Silent (SNP) | VAF 115/236 reads (49%) | catalogued as COSV64202713, COSV64202725; called by muse, mutect2, varscan2
- LRRIQ1 | c.1362G>A p.Q454= | Silent (SNP) | VAF 98/440 reads (22%) | catalogued as COSV67837442; called by muse, mutect2, varscan2
- MARF1 | c.2331G>A p.S777= | Silent (SNP) | VAF 59/223 reads (26%) | catalogued as rs1265366025, COSV60028317; called by muse, mutect2, varscan2
- MDN1 | c.6198G>A p.G2066= | Silent (SNP) | VAF 55/243 reads (23%) | catalogued as COSV65529227; called by muse, mutect2, varscan2
- MTG2 | c.892A>C p.R298= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV63694736; called by muse, mutect2, varscan2
- OR8J3 | c.747G>T p.T249= | Silent (SNP) | VAF 84/299 reads (28%) | catalogued as COSV56880098, COSV56881389; called by muse, mutect2, varscan2
- OVCH1 | c.2631C>T p.L877= | Silent (SNP) | VAF 58/213 reads (27%) | catalogued as COSV58967478; called by muse, mutect2, varscan2
- PCDHB16 | c.2253C>T p.Y751= | Silent (SNP) | VAF 40/190 reads (21%) | catalogued as rs564789192, COSV53369981; called by muse, mutect2, varscan2
- PDK2 | c.871C>A p.R291= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV50304758, COSV50304928; called by muse, mutect2, varscan2
- PGK2 | c.306A>G p.A102= | Silent (SNP) | VAF 111/431 reads (26%) | catalogued as COSV59165412; called by muse, mutect2, varscan2
- PLBD1 | c.381G>A p.T127= | Silent (SNP) | VAF 58/263 reads (22%) | catalogued as COSV53695951, COSV99554236; called by muse, mutect2, varscan2
- RALGAPA2 | c.2562C>T p.G854= | Silent (SNP) | VAF 35/180 reads (19%) | catalogued as COSV52509384; called by muse, mutect2, varscan2
- RAPGEF4 | c.729C>T p.D243= | Silent (SNP) | VAF 48/229 reads (21%) | catalogued as rs780656684, COSV51412230; called by muse, mutect2, varscan2
- RHOBTB3 | c.237T>C p.F79= | Silent (SNP) | VAF 22/290 reads (8%) | catalogued as COSV66102890; called by muse, mutect2
- RTL8B | c.60G>A p.A20= | Silent (SNP) | VAF 44/191 reads (23%) | catalogued as rs1353186472, COSV66954484; called by muse, mutect2, varscan2
- RYR3 | c.189C>A p.L63= | Silent (SNP) | VAF 39/155 reads (25%) | catalogued as COSV66806350; called by muse, mutect2, varscan2
- RYR3 | c.12462C>T p.D4154= (on ENST00000389232; = p.D4155= on NM_001036.6) | Silent (SNP) | VAF 63/235 reads (27%) | catalogued as COSV66806358; called by muse, mutect2, varscan2
- SCN4A | c.4644C>T p.S1548= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs751973449, COSV71127890; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SIX6 | c.483C>T p.L161= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100576534, COSV59803481; called by muse, mutect2
- SLC1A7 | c.906C>T p.C302= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs750126082, COSV65201132; called by muse, mutect2, varscan2
- SMYD2 | c.849C>T p.S283= | Silent (SNP) | VAF 47/350 reads (13%) | catalogued as rs146944968, COSV65291152; called by muse, mutect2, varscan2
- SNAP47 | c.504G>A p.T168= | Silent (SNP) | VAF 34/173 reads (20%) | catalogued as rs766889337, COSV59919841; called by muse, mutect2, varscan2
- STX17 | c.306A>G p.T102= | Silent (SNP) | VAF 99/378 reads (26%) | catalogued as COSV52285639; called by muse, mutect2, varscan2
- TFAP2C | c.1224G>A p.A408= | Silent (SNP) | VAF 56/205 reads (27%) | catalogued as rs111436406, COSV52373039; called by muse, mutect2, varscan2
- TMEM177 | c.69C>A p.S23= | Silent (SNP) | VAF 32/283 reads (11%) | catalogued as COSV55609552; called by muse, mutect2, varscan2
- TMPRSS15 | c.2289T>A p.I763= | Silent (SNP) | VAF 22/288 reads (8%) | catalogued as COSV53047822; called by muse, mutect2
- TOP2B | c.4764A>T p.S1588= (on ENST00000264331 / NM_001330700.2; = p.S1583= on NM_001068.3) | Silent (SNP) | VAF 37/157 reads (24%) | catalogued as COSV51976372; called by muse, mutect2, varscan2
- TSC1 | c.1974C>T p.D658= | Silent (SNP) | VAF 51/187 reads (27%) | catalogued as rs118203608; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- TUT4 | c.1407G>A p.V469= | Silent (SNP) | VAF 109/379 reads (29%) | catalogued as COSV57119112; called by muse, mutect2, varscan2
- TXNDC11 | c.1458C>T p.S486= (on ENST00000356957 / NM_001303447.2; = p.S459= on NM_015914.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 51/205 reads (25%) | catalogued as rs1468175957, COSV51602713; called by muse, mutect2, varscan2
- XPR1 | c.1611C>T p.F537= | Silent (SNP) | VAF 131/753 reads (17%) | catalogued as rs758084024, COSV62560084; called by muse, mutect2, varscan2
- ZPBP | c.1047G>A p.T349= | Silent (SNP) | VAF 95/448 reads (21%) | catalogued as rs564152314, COSV50432636; called by muse, mutect2, varscan2
- CTNNA2 | c.1057-79597dup | Intron (INS) | VAF 19/78 reads (24%) | catalogued as rs1295992907; called by mutect2, varscan2
- EHMT1 | chr9:137838509 del C | 3'Flank (DEL) | VAF 16/56 reads (29%) | catalogued as rs749169251; called by mutect2, pindel, varscan2
- JAKMIP1 | chr4:6048871 ins A | 3'Flank (INS) | VAF 21/106 reads (20%) | called by mutect2, pindel, varscan2
- RBM44 | c.-98-2821del | Intron (DEL) | VAF 28/128 reads (22%) | catalogued as rs746070623, COSV57627686; called by mutect2, varscan2
- RN7SL176P | chr12:100157586 del C | 3'Flank (DEL) | VAF 22/90 reads (24%) | called by mutect2, pindel, varscan2
- SPATA13 | c.290-5336del | Intron (DEL) | VAF 52/196 reads (27%) | catalogued as rs749470297; called by mutect2, varscan2
- STARD7-AS1 | n.1555A>G | RNA (SNP) | VAF 50/169 reads (30%) | called by muse, mutect2, varscan2
- UBTFL2 | n.817A>C | RNA (SNP) | VAF 71/361 reads (20%) | called by muse, mutect2, varscan2
- VPS11 | c.-599G>T | 5'UTR (SNP) | VAF 14/47 reads (30%) | catalogued as COSV56184771, COSV56186847; called by muse, mutect2, varscan2
